Surgical pathology report (de-identified scan), TCGA case TCGA-YH-A8SY, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Stanford University, specimen TCGA-YH-A8SY-01A (Primary Tumor).

[page 1 of 3]
Sex: F

Adm

Results: SURGICAL PROCEDURE (Order)

Status: Edited

Entry Date

Result Narrative

***** THIS IS AN AMENDED REPORT *****

ICD-0.3

Accession No:

SPECIMEN SUBMITTED:

A. GALLBLADDER

B. WHIPPLE SPECIMEN

Adenocarcinoma NOS 8140/3
Site: Pancreas head C25.2
J 5/19/14

Amendment Note: An amendment is issued to correct the TNM staining (pT3). The diagnosis is otherwise unchanged. The changes are italicized.

CLINICAL HISTORY: Per prior biopsy adenocarcinoma in the pancreas.
OPERATION: Pylorus preserving pancreaticoduodenectomy

CLINICAL DIAGNOSIS: Pancreatic mass

GROSS DESCRIPTION: Two specimens are received labeled with the patient's name and medical record number.

The first specimen labeled "gallbladder" is received in formalin and consists of a single piece of tan, soft tissue measuring 8.1 x 3.0 x 2.2 cm representing a gallbladder. Grossly, a 1.8 cm greatest dimension green gallstone is identified. Representative sections are submitted in cassette A1.

The second specimen labeled "Whipple specimen" is received fresh from the OR and consists of a piece of small bowel with attached pancreas measuring 32 x 7 x 5 cm. The uncinata margin is inked in blue, the vascular growth is inked in black and the pancreatic resection margin is inked in green. The common bile duct and pancreatic duct are probed. The specimen is incised on the anterior aspect and a palpable firm, tan, well circumscribed mass is revealed measuring 4.1 x 3.5 x 3.1 cm. Sections are submitted as follows: B1 distal duodenal margin, B2 proximal duodenal margin, B3 bile duct margin, B4-5 pancreatic resection margin, amputated and submitted on edge, B6-7 uncinata margin, amputated and submitted on edge, B8 full cross section of tumor from green ink to the duodenum, B9 cross-section of tumor to black ink, B10 tumor surrounding common bile duct to black ink, B11 representative section of tumor, B12 normal appearing pancreas, B13-21 peripancreatic fat for lymph nodes.

COMMENT: Histological sections show pancreatic adenocarcinoma centered around the pancreatic duct. Sections of the residual pancreatic parenchyma show fat necrosis and chronic pancreatitis.

PANCREAS CARCINOMA SUMMARY
Site Pancreas head

DOB:

Printed by

[page 2 of 3]
Specimen Type Whipple specimen
Tumor Type Adenocarcinoma
Size (cm) 4.1
Grade Moderately differentiated
Associated Lesions Including PanIN Not identified
Common Bile Duct Margin Negative
Distal Pancreatic Margin Positive
Posterior Margin Negative
Retroperitoneal/Uncinate Process Margin Negative, greater than 0.5
cm
Perineural Invasion Present
Lymphovascular Invasion Present
Lymph Node Status Sixteen out of twenty-seven lymph nodes positive
for carcinoma (16/27)
Largest Metastatic Focus 1.0 cm
Extracapsular Extension Present
Distant Metastasis N/A
TNM (AJCC, 7th Edition) pT3 pN1

DIAGNOSIS:

Gallbladder, resection

-- chronic cholecystitis and cholelithiasis

Pancreas, PANCREATICOUDUODENECTOMY

-- INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED, SIZE 4.1
CM, EXTENDING INTO THE PERIPANCREATIC FAT, INVOLVING DISTAL

PANCREATIC RESECTION MARGIN (SEE SUMMARY TABLE AND COMMENT)

-- CARCINOMA IN SIXTEEN OUT OF TWENTYSEVEN LYMPH NODES (16/27)

I have reviewed the specimen and agree with the interpretation
above.

Pathologist

Electronically signed

Amendment #1

Pathologist

Electronically signed

Result HistorySURGICAL PROCEDURE (Order #onOrder Result History Report.**Components Information**SURGICAL PROCEDURE (Order #on**Provider Information**

Ordering User

Incoming Clinical Results

Authorizing Provider

Lab Information**Collection Information**

Collection Date

Collection Time

Order Details

Printed by

[page 3 of 3]
Parent Order ID

Child Order ID

Lab IDs

Specimen #

Patient Release Status:

This result is not viewable by the patient.

Additional Information

Specimen ID

Bill Type

Client ID

Additional InformationSpecimen Date
TakenSpecimen Time
TakenSpecimen
Received DateSpecimen
Received Time

Result Date

Result Time

DOB:
Adm:

Sex: F

Order**SURGICAL PROCEDURE**

(Order)

Patient Information

Patient Name

MRN

Sex
Female

DOB

SSN

Unit

Room

Bed

Provider Information

Ordering User

Authorizing Provider

Results, Incoming Clinical

Admitting Provider

Order DetailsFrequency
ONCEPriority
RoutineOrder Class
Normal**Order Information**

Order Date/Time

Physician Start Date/Time

Account Information**Collection Information**

Collected By:

Collect Date:

Collect Time:

Source: NCI Genomic Data Commons file ab1c8b30-4c75-4829-bdd1-f3a323e531cf (TCGA-YH-A8SY.F26B8F86-CC18-4B90-BD82-CC010A144681.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).